Somatic mutation profile of tumor specimen ALCH-B37W-TTP1-A (aliquot ALCH-B37W-TTP1-A-1-0-D-A780-36) from ALCHEMIST case ALCH-B37W, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 78.0 years (28,507 days).
Specimen ALCH-B37W-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7239b1b8-e3fe-4c50-b909-897c7bf9d225.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B37W-NB1-A (Blood Derived Normal), aliquot ALCH-B37W-NB1-A-1-0-D-A780-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49d6b8ee-4d38-4d2c-832c-b13832233be4

The open-access MAF lists 80 somatic variants for this specimen: 57 protein-altering or splice-affecting, 14 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 14, Intron 6, Nonsense Mutation 5, Frame Shift Del 4, 5'Flank 2, Splice Site 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 16/172 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- TP53 | c.445del p.S149Pfs*21 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | catalogued as rs1064793929, COSV52688587, COSV52700895; ClinVar: pathogenic; called by mutect2, varscan2
- WDR35 | c.1579C>T p.Q527* (on ENST00000345530 / NM_001006657.2; = p.Q516* on NM_020779.4) | Nonsense Mutation (SNP) | VAF 9/254 reads (4%) | catalogued as rs1050086118; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ACACA | c.5507G>A p.G1836D | Missense Mutation (SNP) | VAF 25/197 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs1282194505; called by muse, mutect2, varscan2
- ATP13A3 | c.101T>C p.L34S | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.16); catalogued as rs1157828784; called by muse, mutect2
- CACNA1S | c.2946G>C p.Q982H | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.049); catalogued as COSV62937644; called by muse, mutect2, varscan2
- COL6A6 | c.3718G>A p.A1240T | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs897032757, COSV62035636; called by muse, mutect2, varscan2
- CYLC1 | c.304C>T p.H102Y | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV61413593; called by muse, mutect2
- FER1L6 | c.1801del p.E601Rfs*11 | Frame Shift Del (DEL) | VAF 12/108 reads (11%) | catalogued as COSV101205349; called by mutect2, pindel
- HEATR1 | c.3166G>A p.E1056K | Missense Mutation (SNP) | VAF 6/152 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs919467404; called by muse, mutect2
- KCNT2 | c.717del p.S241Lfs*19 | Frame Shift Del (DEL) | VAF 32/128 reads (25%) | catalogued as COSV54063344, COSV54074161; called by mutect2, pindel, varscan2
- LMF1 | c.1141C>T p.P381S | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV51902868; called by muse, mutect2, varscan2
- LMTK2 | c.3581C>T p.T1194M | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1032225339, COSV51990551; called by muse, mutect2, varscan2
- NCOR1 | c.2930G>A p.R977Q | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.921); catalogued as rs753151137; called by muse, mutect2, varscan2
- OR2G6 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV58574543; called by muse, mutect2, varscan2
- PJA1 | c.1576G>A p.A526T (on ENST00000361478 / NM_145119.4; = p.A338T on NM_022368.5) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100824626; called by muse, mutect2, varscan2
- RSPRY1 | c.550T>G p.L184V | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV68027992; called by muse, mutect2, varscan2
- SCN4A | c.1190T>A p.L397* | Nonsense Mutation (SNP) | VAF 8/102 reads (8%) | catalogued as rs1555604349; called by muse, mutect2
- TMEM132C | c.2625del p.D875Efs*46 | Frame Shift Del (DEL) | VAF 3/23 reads (13%) | catalogued as COSV59432319; called by pindel, varscan2
- USPL1 | c.2981G>T p.R994M | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.225); catalogued as COSV55002712; called by muse, mutect2, varscan2
- ZNF43 | c.1697A>G p.Y566C | Missense Mutation (SNP) | VAF 11/242 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs926974599; called by muse, mutect2
- AC098582.1 | c.118G>T p.A40S | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- ATP5F1A | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- BPIFB2 | c.494T>G p.I165S | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- CLEC5A | c.475T>A p.F159I | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- CLTB | c.82C>A p.L28M | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ENPP1 | c.2167G>C p.V723L | Missense Mutation (SNP) | VAF 13/222 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2
- FAT2 | c.11224C>T p.H3742Y | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, varscan2
- FRMD4B | c.743T>C p.I248T | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- GFI1B | c.683C>A p.A228D | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); called by muse, varscan2
- KCNT1 | c.866G>A p.C289Y (on ENST00000488444; = p.C308Y on NM_020822.3) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- KRTAP4-16 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0); called by muse, varscan2
- LMBRD1 | c.1355G>C p.S452T (on ENST00000649011; = p.S430T on NM_018368.4) | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.03); called by muse, mutect2
- LRP1B | c.11599T>G p.C3867G | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MFGE8 | c.961G>A p.V321I | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- MYL12A | c.257T>G p.L86R | Missense Mutation (SNP) | VAF 27/238 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NELFCD | c.647C>G p.T216S (on ENST00000602795; = p.T198S on NM_198976.4) | Missense Mutation (SNP) | VAF 14/320 reads (4%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.973); called by muse, mutect2
- NLGN1 | c.1269T>A p.Y423* | Nonsense Mutation (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- NSRP1 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 8/194 reads (4%) | called by muse, mutect2
- OR13H1 | c.381C>A p.S127R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- PSTK | c.483T>A p.Y161* | Nonsense Mutation (SNP) | VAF 5/70 reads (7%) | called by muse, mutect2
- RELN | c.243C>A p.S81R | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SDF2L1 | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SFSWAP | c.1549-22_1549-2del p.X517_splice | Splice Site (DEL) | VAF 20/124 reads (16%) | called by mutect2, pindel
- SGO2 | c.1419G>T p.M473I | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ST3GAL2 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 16/56 reads (29%) | PolyPhen possibly damaging (0.718); called by muse, mutect2
- TMEM196 | c.533+1G>T p.X178_splice | Splice Site (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- TRHR | c.845A>G p.Y282C | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.34565C>T p.P11522L (on ENST00000591111; = p.P10595L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/216 reads (9%) | PolyPhen benign (0.006); called by muse, mutect2
- UBAP2L | c.2134C>G p.R712G | Missense Mutation (SNP) | VAF 35/255 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- USH2A | c.3961C>A p.Q1321K | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- USP11 | c.1538G>T p.R513L (on ENST00000218348; = p.R470L on NM_001371072.1) | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.33); called by muse, mutect2
- USP9X | c.3785A>T p.E1262V | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.046); called by muse, mutect2
- VCAM1 | c.1984G>C p.D662H | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF101 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.703); called by muse, mutect2
- ZNF639 | c.1018C>T p.H340Y | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); called by muse, mutect2
- ZNF99 | c.2193A>T p.K731N | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANK1 | c.3189C>T p.F1063= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as rs1291901143, COSV55873095; called by muse, mutect2, varscan2
- CABP2 | c.147G>A p.S49= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs1330939152, COSV53709578, COSV99590683; called by muse, mutect2
- CSMD3 | c.3390C>A p.T1130= (on ENST00000297405 / NM_001363185.1; = p.T1026= on NM_052900.3) | Silent (SNP) | VAF 16/90 reads (18%) | called by muse, mutect2, varscan2
- DEGS1 | c.531C>T p.I177= | Silent (SNP) | VAF 56/279 reads (20%) | called by muse, mutect2, varscan2
- GPRASP1 | c.825C>A p.P275= | Silent (SNP) | VAF 15/116 reads (13%) | called by mutect2, varscan2
- IGKV1-8 | c.285C>A p.I95= | Silent (SNP) | VAF 6/122 reads (5%) | called by muse, mutect2
- INSIG2 | c.516A>G p.L172= | Silent (SNP) | VAF 7/108 reads (6%) | catalogued as rs1257100765; called by muse, mutect2
- OLFML2B | c.1518C>A p.T506= | Silent (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- RHOXF2B | c.321C>T p.S107= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs1555996277; called by muse, mutect2, varscan2
- RYR2 | c.9213C>A p.T3071= | Silent (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- USH2A | c.12738T>A p.A4246= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as rs913081394; called by muse, mutect2
- ZNF292 | c.8044T>C p.L2682= | Silent (SNP) | VAF 11/217 reads (5%) | called by muse, mutect2
- ZNF571 | c.90G>A p.L30= | Silent (SNP) | VAF 15/110 reads (14%) | called by muse, mutect2
- ZNF804B | c.1887C>T p.S629= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV100306130; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849627 T>A | 5'Flank (SNP) | VAF 15/338 reads (4%) | called by muse, mutect2
- EXOC7 | c.1515+57C>G | Intron (SNP) | VAF 4/44 reads (9%) | catalogued as rs1375145249, COSV58745064; called by mutect2, varscan2
- FTSJ1 | c.122-48G>A | Intron (SNP) | VAF 7/57 reads (12%) | catalogued as rs782346310; called by muse, mutect2, varscan2
- LYG2 | c.520+541T>C | Intron (SNP) | VAF 17/130 reads (13%) | called by muse, mutect2, varscan2
- PCBP2 | c.376-601C>G | Intron (SNP) | VAF 4/26 reads (15%) | catalogued as rs757684601; called by mutect2, varscan2
- PPM1B | c.1134+342C>T | Intron (SNP) | VAF 15/91 reads (16%) | catalogued as rs374642609; called by muse, mutect2, varscan2
- SAMD3 | c.654+812G>C | Intron (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- UCHL5 | chr1:193059844 A>T | 5'Flank (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2, varscan2
- ZNF207 | c.-29C>T | 5'UTR (SNP) | VAF 8/55 reads (15%) | catalogued as rs766585515; called by muse, mutect2, varscan2
